Somatic mutation profile of tumor specimen TCGA-DJ-A3UO-01A (aliquot TCGA-DJ-A3UO-01A-11D-A22D-08) from TCGA case TCGA-DJ-A3UO, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage IVA; Age at diagnosis: 63.8 years (23,292 days).
Specimen TCGA-DJ-A3UO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8b67f491-d420-4763-8f35-44c15f78c2b2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A3UO-10A (Blood Derived Normal), aliquot TCGA-DJ-A3UO-10A-01D-A22D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ede0669-ff16-4d81-9b91-2933115bcee9

The open-access MAF lists 10 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 9, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ECEL1 | c.1274C>T p.A425V | Missense Mutation (SNP) | VAF 51/137 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.231); catalogued as COSV58812318; called by muse, mutect2, varscan2
- ENPP6 | c.1199C>T p.P400L | Missense Mutation (SNP) | VAF 66/228 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs775018210, COSV57068200; called by muse, mutect2, varscan2
- KCNA5 | c.787T>G p.S263A | Missense Mutation (SNP) | VAF 42/332 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV52905780, COSV99364122; called by muse, mutect2, varscan2
- KRBA2 | c.473G>T p.R158L | Missense Mutation (SNP) | VAF 43/273 reads (16%) | SIFT tolerated (0.86); PolyPhen benign (0.007); catalogued as COSV58779059; called by muse, mutect2, varscan2
- OR3A3 | c.583C>A p.Q195K | Missense Mutation (SNP) | VAF 63/182 reads (35%) | SIFT tolerated (0.81); PolyPhen benign (0.021); catalogued as COSV52167484; called by muse, mutect2, varscan2
- SLC22A16 | c.1700C>G p.A567G | Missense Mutation (SNP) | VAF 88/224 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.237); catalogued as COSV100397912, COSV57930048; called by muse, mutect2, varscan2
- ZNF142 | c.5349C>G p.H1783Q (on ENST00000411696 / NM_001379660.1; = p.H1583Q on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs760564661, COSV68743757; called by muse, mutect2, varscan2
- ZNF263 | c.1106C>T p.P369L | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as rs541895788, COSV54596555, COSV99526813; called by muse, mutect2, varscan2
- TAPBP | c.1191G>A p.E397= | Silent (SNP) | VAF 57/152 reads (38%) | catalogued as COSV70457194; called by muse, mutect2, varscan2
